Somatic mutation profile of tumor specimen BA2498D (aliquot aq-BA2498D) from BEATAML1.0 case 2102, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.0 years (28,838 days).
Specimen BA2498D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3797ca5-d426-42b0-a5ab-3b04b9d6403f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2683D (Solid Tissue Normal), aliquot aq-BA2683D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cdfefe9-793f-4c86-8a4b-c4dfb71860a8

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42EP5 | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1248868309; called by muse, mutect2, varscan2
- CHMP1A | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs773029258, COSV53682260; called by muse, mutect2, varscan2
- KDM4B | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV50214073; called by muse, mutect2, varscan2
- MYH14 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs750639438; called by muse, mutect2, varscan2
- RBM27 | c.2167A>G p.T723A | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs555068694; called by muse, mutect2, varscan2
- ROS1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs768790336, COSV63856637; called by muse, mutect2, varscan2
- CADPS | c.1118G>T p.S373I | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CHD5 | c.5743G>A p.G1915S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNMT3A | c.2725T>G p.F909V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FERMT2 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM4C | c.594C>A p.S198R | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSC2 | c.2838-8C>G | Splice Region (SNP) | VAF 79/172 reads (46%) | called by muse, mutect2, varscan2
- NLRX1 | c.189C>T p.P63= | Silent (SNP) | VAF 65/162 reads (40%) | catalogued as rs561434742; called by muse, mutect2, varscan2
- STK31 | c.2592C>T p.N864= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as rs375943570; called by muse, varscan2
- AC068473.1 | n.473C>T | RNA (SNP) | VAF 48/83 reads (58%) | catalogued as rs1050865712; called by muse, mutect2, varscan2
